Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H9, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H9-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. LYMPH NODE, PORTAL, EXCISION:
Negative for metastatic carcinoma.
- B. LIVER, SEGMENT 4 LESION, BIOPSY:
Fragment of liver parenchyma with macro and microvesicular steatosis and chronic portal inflammation.
There is no evidence of malignancy.
- C. LIVER, SUPERIOR SEGMENT 4, BIOPSY:
Fragment of liver parenchyma with minimal portal inflammation.
There is no evidence of malignancy.
- D. LIVER, ADDITIONAL SUPERIOR SEGMENT 4, BIOPSY:
Fragment of liver parenchyma with chronic portal inflammation.
There is no evidence of malignancy.
- E. LIVER, SEGMENT 6, BIOPSY:
Fragment of liver parenchyma with microvesicular steatosis and portal inflammation.
There is no evidence of malignancy.
- F. LIVER, SEGMENT 6, RESECTION:
Hepatocellular carcinoma, moderately differentiated, trabecular architecture (see key pathologic findings).

ICD-0-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0
817013
JW 4/28/14

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Key Pathological Findings

F: Liver, Resection

Specimen:

Liver

PROCEDURE:

Partial hepatectomy

*Minor hepatectomy (less than 3 segments)

TUMOR SIZE:

Greatest dimension: 4.0 cm

*Additional dimensions: 3.8 x 3.5 cm

TUMOR FOCALITY:

Solitary (specify location): segment 6

HISTOLOGIC TYPE:

[page 2 of 3]
Hepatocellular carcinoma
HISTOLOGIC GRADE:
G1: Well differentiated
TUMOR EXTENSION (select all that apply):
Tumor confined to liver
PRIMARY TUMOR (pT):
pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
REGIONAL LYMPH NODES (pN):
pN0: No regional lymph node metastasis
DISTANT METASTASIS (pM):
pMX: Cannot be assessed
MARGINS:
Parenchymal margin uninvolved by invasive carcinoma
*VENOUS (LARGE VESSEL) INVASION (V):
*Absent
*ADDITIONAL PATHOLOGIC FINDINGS:
*Hepatitis (specify type): Hepatitis C

Specimen(s) Received

A PORTAL LYMPH NODE FS
B SEGMENT 4 LESION FS
C SUPERIOR SEGMENT 4 FS
D ADDITIONAL SUPERIOR SEGMENT 4 FS
E SEGMENT 6 FS
F LIVER RESECTION SEGMENT 6

Clinical History

None given.

Preoperative Diagnosis

Hepatocellular carcinoma.

Intraoperative Consultation

FSA1. PORTAL LYMPH NODE:
Negative.

FSB1. SEGMENT 4 LESION:
Benign liver.

FSC1. SUPERIOR SEGMENT 4 LESION:
Benign liver.

FSD1. ADDITIONAL SUPERIOR SEGMENT 4:
Benign liver.

FSE1. SEGMENT 6:
Benign liver.

[page 3 of 3]
Comment: This frozen section diagnosis/result was communicated to and acknowledged by
in at on

I, , have performed the intraoperative consultation and issued the above
diagnosis.

Gross Description

- A. The specimen is received fresh labeled "portal lymph node". The specimen consists of a single roughly ovoid, rubbery lymph node measuring up to 2.0 cm in greatest dimension. The lymph node is bisected and is submitted entirely for frozen section as FSA1.
- B. The specimen is received fresh labeled "segment 4 lesion". The specimen consists of a single core biopsy fragment of tan brown tissue measuring 0.7 cm in length and less than 0.1 cm in diameter. The specimen is submitted entirely for frozen section as FSB1.
- C. The specimen is received fresh labeled "superior segment 4". The specimen consists of a single core biopsy fragment of tan brown tissue measuring 1.1 cm in length and less than 0.1 cm in diameter. The specimen is submitted entirely for frozen section as FSC1.
- D. The specimen is received fresh labeled "additional superior segment 4". The specimen consists of a single core biopsy fragment of tan brown tissue measuring up to 0.7 cm in length, which is submitted entirely for frozen section as FSD1.
- E. The specimen is received fresh labeled "segment 6". The specimen consists of a single core biopsy fragment of tan brown tissue measuring 0.5 cm in length and less than 0.1 cm in diameter. The specimen is submitted entirely for frozen section as FSE1.
- F. The specimen is received fresh labeled "liver resection segment 6". The specimen consists of an irregular, unoriented fragment of liver parenchyma measuring 6.5 x 5.5 x 4.0 cm and weighs 79.0 grams. The capsule of the portion of liver is tan red brown, smooth and glistening. The parenchymal resection margin is shaggy, cauterized and is marked with black ink. The specimen is serially sectioned to reveal an irregular to roughly ovoid, well-defined, solid intraparenchymal tumor nodule, which measures 4.0 x 3.8 x 3.5 cm. The tumor is 0.3 cm from the closest parenchymal resection margin. The tumor partially bulges but does not appear to extend through the hepatic capsule. The cut surface of the tumor is variegated, pink tan to brown, focally hemorrhagic and lobulated. The hepatic capsule overlying tumor is marked with blue ink. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 6 cassettes as follows:
F1-F3: Tumor in relation to closest parenchymal resection margin
F4-F6: Additional sections of the tumor bulging hepatic capsule

Source: NCI Genomic Data Commons file 1524b824-8f81-4645-b9bd-b2b34dcbf447 (TCGA-2Y-A9H9.36C343AC-443B-4196-8B6D-7D9213F2DAE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).